Gene-level copy-number profile of tumor specimen HTMCP-02-01-01254-01A from CGCI case HTMCP-02-01-01254, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage I.
Specimen HTMCP-02-01-01254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c1382964-6356-4968-bc97-dcd3bbd61263.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-01-01254-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/fe60588d-8546-45b8-a3a3-0417a4fa2915

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 558; copy number 1: 20,216; copy number 2: 33,202; copy number 3: 1,848; copy number 4: 2,956; copy number 5: 60; copy number 6: 47; copy number 7: 1; copy number 9: 13.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes (within-gene range 0–1): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:12,791,397–12,841,357, 4 genes: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–1): PRAMEF2.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr2:191,154,118–191,246,172, 3 genes (within-gene range 0–1): AC079777.1, HMGB1P27, AC092614.1.
- chr2:205,681,990–205,798,133, 2 genes: NRP2, AC007362.1.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–1): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:73,567,620–73,582,918, 3 genes: ACOT2, NT5CP1, AC005225.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 121 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,811,768–130,812,095, 1 gene, copy number 6: RN7SKP212.
- chr3:189,631,389–190,165,523, 7 genes, copy number 5: TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P.
- chr4:49,486,926–49,589,529, 12 genes, copy number 9: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:21,750,673–22,853,344, 1 gene, copy number 5 (within-gene range 4–5): CDH12.
- chr5:22,139,247–25,445,925, 39 genes, copy number 5: AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr5:52,930,606–53,819,722, 11 genes, copy number 5 (within-gene range 4–5): AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC108114.1, FST, NDUFS4, LINC02105.
- chr14:105,620,506–105,626,066, 1 gene, copy number 5 (within-gene range 1–5): IGHG4.
- chr21:30,642,864–30,718,777, 2 genes, copy number 6: KRTAP20-3, KRTAP21-3.
- chr22:18,951,934–19,724,772, 44 genes, copy number 6: AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1, DGCR2, Y_RNA, DGCR11, AC004461.1, AC004461.2, AC004471.1, AC004471.2, TSSK1A, ESS2, TSSK2, GSC2, LINC01311, SLC25A1, CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62, HIRA, C22orf39, RN7SL168P, MRPL40, AC000068.1, UFD1, AC000068.3, AC000068.2, CDC45, AC000082.1, CLDN5, LINC00895, AC000077.1, AC000067.1, SEPTIN5, AC000093.1, GP1BB.
- chr22:21,379,382–21,396,590, 2 genes, copy number 7–9: Metazoa_SRP, Metazoa_SRP.
- chr22:21,466,423–21,471,269, 1 gene, copy number 5: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 17,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
